TCGA case TCGA-BJ-A45G — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8cb385a-4e5f-4932-944d-04d6ea1bba5a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.8 years (17,831 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 725 days (2.0 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 7; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 2.5; Tumor width measurement: 1.6.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 1 day; Days to treatment end: 1 day; Treatment dose: 101 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 101.4; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 193 days; Disease response: Tumor Free.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Nodular Hyperplasia.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BJ-A45G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-BJ-A45G-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-BJ-A45G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BJ-A45G-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BJ-A45G-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 360 mg.
  Slide TCGA-BJ-A45G-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Nodular Hyperplasia.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 725 days; disease-specific survival: no event (censored), 725 days; progression-free interval: no event (censored), 725 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BJ-A45G-01A-11D-A23T-01): tumor purity 0.78, ploidy 2, whole-genome doublings 0.
